Somatic mutation profile of tumor specimen TCGA-P3-A6SX-01A (aliquot TCGA-P3-A6SX-01A-11D-A34J-08) from TCGA case TCGA-P3-A6SX, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 67.7 years (24,715 days).
Specimen TCGA-P3-A6SX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40ccd7a7-9a66-4df7-8b94-23dccba5ecdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A6SX-10A (Blood Derived Normal), aliquot TCGA-P3-A6SX-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39c27303-8aec-4db1-8bf6-2fccafcb9fe5

The open-access MAF lists 181 somatic variants for this specimen: 141 protein-altering or splice-affecting, 34 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 34, Nonsense Mutation 14, Intron 5, Splice Site 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.489C>G p.Y163* | Nonsense Mutation (SNP) | VAF 45/87 reads (52%) | hotspot (GDC flag); catalogued as rs1567553246, COSV52741368, COSV52741580, COSV52875770, COSV53211332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.6613G>A p.E2205K (on ENST00000614293; = p.E2175K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV99687580; called by muse, mutect2, varscan2
- ABCC6 | c.3109G>C p.E1037Q | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228726; called by muse, mutect2, varscan2
- ABCE1 | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV99668552; called by muse, mutect2, varscan2
- ACAD10 | c.1991G>C p.R664T | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV100564151; called by muse, mutect2, varscan2
- ADAM22 | c.2012T>C p.V671A | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1319342376, COSV99716810; called by muse, mutect2, varscan2
- ADGRB3 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.073); catalogued as COSV65412299; called by muse, mutect2, varscan2
- AGAP6 | c.706G>T p.G236W (on ENST00000374056 / NM_001365867.1; = p.G259W on NM_001077665.2) | Missense Mutation (SNP) | VAF 110/369 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV65017264; called by muse, mutect2, varscan2
- AGXT2 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 79/154 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51489097, COSV99183749; called by muse, mutect2, varscan2
- ARHGAP15 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99710471; called by muse, mutect2, varscan2
- ARMH4 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs752359198, COSV50767287; called by muse, mutect2
- ATP8A2 | c.595A>G p.M199V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs755131806, COSV99681836; called by muse, mutect2, varscan2
- BBS7 | c.1379C>G p.S460* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99144853, COSV99144918; called by muse, mutect2, varscan2
- C12orf43 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV99982517; called by muse, mutect2
- C1orf94 | c.1145C>A p.P382Q (on ENST00000488417 / NM_001134734.2; = p.P192Q on NM_032884.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.919); catalogued as COSV100974912; called by muse, mutect2, varscan2
- CABIN1 | c.2131C>G p.L711V | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99573171; called by muse, mutect2, varscan2
- CARD11 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 11/169 reads (7%) | catalogued as COSV62718431; called by muse, mutect2
- CCDC141 | c.3834T>A p.D1278E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV99836800; called by muse, mutect2, varscan2
- CCDC40 | c.1097T>A p.L366Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99481714; called by muse, mutect2
- CCSER2 | c.41A>C p.K14T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99825922; called by muse, mutect2, varscan2
- CD1E | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV63771377; called by muse, mutect2, varscan2
- CDH4 | c.2724C>A p.D908E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100848783; called by muse, mutect2, varscan2
- CDH9 | c.1901C>G p.A634G | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99144496, COSV99148956; called by muse, mutect2, varscan2
- CEP350 | c.2075C>G p.S692C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100854647; called by muse, mutect2, varscan2
- CHORDC1 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100272025; called by muse, mutect2, varscan2
- CLASP1 | c.3344C>T p.T1115I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99754775; called by muse, mutect2, varscan2
- CLUH | c.3346G>A p.G1116R (on ENST00000435359; = p.G1155R on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101425741, COSV70928113; called by muse, mutect2, varscan2
- CNGB3 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as CM154647, COSV100181056; called by muse, mutect2, varscan2
- COL11A1 | c.4036C>A p.P1346T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100616452; called by muse, mutect2, varscan2
- COL18A1 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.401); catalogued as COSV100700674; called by muse, mutect2, varscan2
- COL4A5 | c.4187A>T p.Q1396L | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100087647; called by muse, mutect2, varscan2
- CPNE3 | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs747157675, COSV99547623; called by muse, mutect2, varscan2
- CPXM1 | c.1453T>A p.W485R | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101013728; called by muse, mutect2
- CRPPA | c.837G>C p.E279D (on ENST00000407010 / NM_001368197.1; = p.E229D on NM_001101417.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as COSV101235385; called by muse, mutect2, varscan2
- CSMD2 | c.5810C>T p.P1937L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771394942, COSV53900171; called by muse, mutect2, varscan2
- DGKB | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs267601385, COSV51766687; called by muse, mutect2, varscan2
- DIS3L | c.1819A>T p.I607F (on ENST00000319212 / NM_001143688.3; = p.I524F on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100055186; called by muse, mutect2, varscan2
- DLG1 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs200751878, COSV100015323; called by muse, mutect2, varscan2
- DMD | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs1203696293, COSV99922231; called by muse, mutect2, varscan2
- DPP4 | c.2152C>G p.Q718E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.226); catalogued as COSV100858857; called by muse, mutect2, varscan2
- DSEL | c.3607C>A p.L1203I | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100025624; called by muse, mutect2, varscan2
- DSEL | c.3512C>A p.T1171N | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100025626; called by muse, mutect2, varscan2
- DUSP10 | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.748); catalogued as COSV100100497; called by muse, mutect2, varscan2
- EIF5B | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV99177237; called by muse, mutect2, varscan2
- ERBB4 | c.840T>A p.N280K | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99623058; called by muse, mutect2, varscan2
- FAT4 | c.14052G>T p.L4684F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100628560; called by muse, mutect2, varscan2
- FBN1 | c.858T>A p.C286* | Nonsense Mutation (SNP) | VAF 176/563 reads (31%) | catalogued as COSV100354981; called by muse, mutect2, varscan2
- FLG | c.3793C>A p.H1265N | Missense Mutation (SNP) | VAF 121/427 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs762882739, COSV64245442; called by muse, mutect2, varscan2
- GDI2 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.451); catalogued as COSV100050462, COSV100050545; called by muse, mutect2, varscan2
- GLUD1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.426); catalogued as COSV99518128; called by muse, mutect2, varscan2
- GRIK2 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 46/150 reads (31%) | catalogued as COSV100025907; called by muse, mutect2, varscan2
- GSTZ1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV99374307, COSV99374437; called by muse, mutect2, varscan2
- H2BC1 | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV99219394; called by muse, mutect2, varscan2
- HIF1A | c.2359A>G p.M787V | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs761301966, COSV100048856; called by muse, mutect2, varscan2
- HMGCR | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV99843243; called by muse, mutect2, varscan2
- HMGXB4 | c.1104C>G p.Y368* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as COSV99330093; called by muse, varscan2
- IFNA10 | c.131T>C p.M44T | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751168118, COSV99497474; called by muse, mutect2, varscan2
- IGKV1D-8 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774226856; called by muse, mutect2, varscan2
- ITPRID1 | c.2992G>C p.G998R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV100086376, COSV100086409; called by muse, mutect2, varscan2
- ITPRID1 | c.2993G>T p.G998V | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV100086379, COSV60071156; called by muse, mutect2, varscan2
- KALRN | c.7351G>C p.D2451H (on ENST00000360013 / NM_001024660.4; = p.D754H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99361990; called by muse, mutect2
- KCNJ1 | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100131340; called by muse, mutect2, varscan2
- KDM6A | c.3519C>A p.Y1173* | Nonsense Mutation (SNP) | VAF 38/72 reads (53%) | catalogued as COSV100938173; called by muse, mutect2, varscan2
- KLHL4 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100909542; called by muse, mutect2, varscan2
- KRT35 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99877770; called by muse, mutect2, varscan2
- LIG3 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV99252575; called by muse, mutect2, varscan2
- LRRN1 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100076273; called by muse, mutect2, varscan2
- MAP2 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99559837; called by muse, mutect2, varscan2
- MCAT | c.974A>T p.K325M | Missense Mutation (SNP) | VAF 129/271 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99295665; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2039C>G p.S680* | Nonsense Mutation (SNP) | VAF 29/171 reads (17%) | catalogued as COSV100825111; called by muse, mutect2, varscan2
- MRI1 | c.1067C>T p.T356I (on ENST00000040663 / NM_001031727.4; = p.T309I on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99237464; called by muse, mutect2, varscan2
- MRTO4 | c.80T>G p.I27R | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV100367471; called by muse, mutect2, varscan2
- MTDH | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1330466562, COSV100292543; called by muse, mutect2, varscan2
- MTHFD2 | c.1025C>G p.S342C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.215); catalogued as COSV99903061; called by muse, mutect2, varscan2
- MUC16 | c.39072T>A p.Y13024* | Nonsense Mutation (SNP) | VAF 48/198 reads (24%) | catalogued as COSV101199870; called by muse, mutect2, varscan2
- MUC16 | c.6767C>A p.P2256H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101199871; called by muse, mutect2, varscan2
- NBEA | c.6589C>T p.L2197F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV59763569; called by muse, mutect2
- NEIL3 | c.1739C>A p.P580H | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99220431; called by muse, mutect2, varscan2
- NHLRC4 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99216086; called by muse, mutect2, varscan2
- NNMT | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs777589054, COSV100248877; called by muse, mutect2, varscan2
- NOTCH2 | c.1204A>C p.T402P | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99863970; called by muse, mutect2, varscan2
- NPAT | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV99586023; called by muse, mutect2, varscan2
- NTRK3 | c.692G>T p.C231F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100446492; called by muse, mutect2, varscan2
- NUTM1 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs972575412, COSV100412297; called by muse, mutect2, varscan2
- OGDHL | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1469103083, COSV100934307; called by muse, mutect2, varscan2
- OR3A3 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV99351357; called by muse, mutect2, varscan2
- OR4A16 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs144905099, COSV59044107; called by muse, mutect2, varscan2
- OR4C13 | c.480C>A p.F160L | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.168); catalogued as rs782002007, COSV73648688; called by muse, mutect2, varscan2
- PCDH10 | c.1963G>T p.E655* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52086607, COSV99993510; called by muse, mutect2, varscan2
- PCDH11X | c.3217C>A p.H1073N | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV100011602, COSV53451050; called by muse, mutect2, varscan2
- PCNX4 | c.1945C>G p.L649V (on ENST00000406854 / NM_001330177.2; = p.L415V on NM_022495.5) | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV100470284; called by muse, mutect2, varscan2
- PFAS | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100118916; called by muse, mutect2, varscan2
- PIK3C2G | c.868A>G p.I290V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs367579213; called by muse, mutect2, varscan2
- PJA2 | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV100754430; called by muse, mutect2, varscan2
- POGZ | c.2333A>G p.Y778C | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762903499, COSV99652746; called by muse, mutect2, varscan2
- PPM1K | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99900970; called by muse, mutect2, varscan2
- PPP1R9A | c.415T>A p.F139I | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as COSV99195555; called by muse, mutect2, varscan2
- PRDM9 | c.891G>T p.K297N | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99690410; called by muse, mutect2, varscan2
- PRPF6 | c.344G>C p.R115T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99411965; called by muse, mutect2, varscan2
- PTGFRN | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.186); catalogued as COSV101277341; called by muse, mutect2, varscan2
- RAB36 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99320732; called by muse, mutect2, varscan2
- RARB | c.521G>A p.C174Y (on ENST00000383772 / NM_001290216.2; = p.C167Y on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.284); catalogued as COSV100412420; called by muse, mutect2
- RBM46 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV99908092; called by muse, mutect2, varscan2
- RIMS1 | c.3391C>T p.R1131* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99326707; called by muse, mutect2
- RPL7A | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV100034683; called by muse, mutect2, varscan2
- RPLP2 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367815234; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100402484; called by muse, mutect2, varscan2
- RYR2 | c.10471C>G p.L3491V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.395); catalogued as rs747700917, COSV100770022; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.3090G>C p.K1030N | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101211960, COSV101212733; called by muse, mutect2, varscan2
- SCTR | c.581T>G p.I194S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99191576; called by muse, mutect2, varscan2
- SLC12A4 | c.3103G>A p.D1035N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs761143750, COSV99863050; called by muse, mutect2, varscan2
- SLC41A2 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as rs1394654011, COSV99316492; called by muse, mutect2
- SLITRK1 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100999945; called by muse, mutect2, varscan2
- SLITRK6 | c.2414A>G p.Y805C | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101233232; called by muse, mutect2
- SNX4 | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV52538912; called by muse, mutect2, varscan2
- STIP1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as rs149913210; called by muse, mutect2, varscan2
- SYNDIG1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100965263; called by muse, mutect2, varscan2
- SYNE1 | c.12695G>A p.R4232K (on ENST00000367255 / NM_182961.4; = p.R4161K on NM_033071.3) | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.365); catalogued as rs886043857, COSV99563383; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACC2 | c.2105A>C p.Q702P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100552311; called by muse, mutect2, varscan2
- TAF6 | c.171C>G p.F57L | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV100693388, COSV59842969; called by muse, mutect2
- TCEA2 | c.518-1C>T p.X173_splice | Splice Site (SNP) | VAF 15/132 reads (11%) | catalogued as COSV58657139; called by muse, mutect2, varscan2
- TENM3 | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.775); catalogued as COSV101305110; called by muse, mutect2, varscan2
- THAP4 | c.140G>A p.W47* | Nonsense Mutation (SNP) | VAF 45/212 reads (21%) | catalogued as COSV101126028; called by muse, mutect2, varscan2
- TKTL1 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV54211978; called by muse, mutect2, varscan2
- TMCO3 | c.456A>C p.E152D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV100952323; called by muse, mutect2, varscan2
- TRIM21 | c.311A>T p.E104V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99587689; called by muse, mutect2, varscan2
- UBE3D | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV52753032, COSV52753354, COSV99389030; called by muse, mutect2, varscan2
- UNC13C | c.3931C>A p.Q1311K | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99516928; called by muse, mutect2, varscan2
- USP12 | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761208302, COSV99997582; called by muse, mutect2, varscan2
- VCAM1 | c.1094A>C p.N365T | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV99658538; called by muse, mutect2, varscan2
- VPS13C | c.11025T>A p.D3675E (on ENST00000644861 / NM_020821.3; = p.D3632E on NM_017684.5) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99828433; called by muse, mutect2, varscan2
- WDHD1 | c.3189+1G>A p.X1063_splice | Splice Site (SNP) | VAF 91/178 reads (51%) | catalogued as COSV100777576; called by muse, mutect2, varscan2
- WIPF2 | c.1241A>G p.Y414C | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60272219; called by muse, mutect2, varscan2
- XIRP2 | c.6814G>A p.A2272T (on ENST00000628543; = p.A2447T on NM_152381.6) | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1388189746, COSV99742679; called by muse, mutect2, varscan2
- XPNPEP3 | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100846699; called by muse, mutect2, varscan2
- XPO1 | c.564A>T p.Q188H | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101294208; called by muse, mutect2, varscan2
- ZNF516 | c.2981C>G p.A994G | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101487278; called by muse, mutect2, varscan2
- ZNF8 | c.759G>C p.Q253H | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV99544300; called by muse, mutect2, varscan2
- MYO19 | c.1433G>A p.G478E | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUDT13 | c.309dup p.A104Sfs*11 | Frame Shift Ins (INS) | VAF 36/142 reads (25%) | called by mutect2, pindel, varscan2
- POTEA | c.1120C>G p.P374A (on ENST00000519951 / NM_001005365.2; = p.P328A on NM_001002920.1) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- AGXT2 | c.1266G>C p.R422= | Silent (SNP) | VAF 78/152 reads (51%) | catalogued as COSV99183750; called by muse, mutect2, varscan2
- CEP192 | c.6291C>G p.V2097= | Silent (SNP) | VAF 60/214 reads (28%) | catalogued as COSV100381196; called by muse, mutect2, varscan2
- CILP | c.3327C>T p.S1109= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1286018465, COSV99973363; called by muse, mutect2, varscan2
- COL4A5 | c.3507C>T p.P1169= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs764389956, COSV100087645; ClinVar: likely benign; called by muse, varscan2
- CTNNA2 | c.1083T>C p.P361= | Silent (SNP) | VAF 24/178 reads (13%) | catalogued as COSV100560588; called by muse, varscan2
- CTNNA3 | c.1452T>C p.R484= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as COSV101049089; called by muse, mutect2, varscan2
- DNAH9 | c.3795C>A p.I1265= | Silent (SNP) | VAF 56/161 reads (35%) | catalogued as COSV52377962, COSV99305780; called by muse, mutect2, varscan2
- ENO3 | c.936C>T p.N312= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99236480; called by muse, mutect2, varscan2
- ERGIC2 | c.174A>T p.T58= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV100791968; called by muse, mutect2, varscan2
- FOXA3 | c.732G>A p.A244= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as rs776353999, COSV100141378; called by muse, varscan2
- GARRE1 | c.2979C>T p.S993= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV100209406; called by muse, mutect2, varscan2
- GIMAP7 | c.99C>A p.I33= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100543655, COSV57960878; called by muse, mutect2, varscan2
- GRIN3A | c.2256C>T p.F752= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs267602060, COSV100701487; called by muse, mutect2, varscan2
- HELZ | c.4050C>T p.H1350= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs767925397, COSV62376646; called by muse, mutect2, varscan2
- HEXD | c.24G>A p.Q8= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV100027718; called by muse, mutect2, varscan2
- KCNC1 | c.420C>T p.G140= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV56397134; called by muse, mutect2, varscan2
- KIT | c.2415C>A p.I805= | Silent (SNP) | VAF 50/163 reads (31%) | catalogued as COSV55426406, COSV99854220; called by muse, mutect2, varscan2
- KRTAP5-11 | c.156T>C p.C52= | Silent (SNP) | VAF 69/467 reads (15%) | catalogued as COSV100651801; called by muse, mutect2, varscan2
- MAGEB1 | c.204C>A p.T68= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100974960; called by muse, mutect2
- MAP3K6 | c.1401C>G p.L467= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV62889941; called by muse, mutect2, varscan2
- METTL3 | c.192C>T p.S64= | Silent (SNP) | VAF 154/278 reads (55%) | catalogued as COSV99398273; called by muse, mutect2, varscan2
- MYLK4 | c.489C>A p.L163= | Silent (SNP) | VAF 26/213 reads (12%) | catalogued as COSV99193784; called by muse, mutect2, varscan2
- OR5AC2 | c.426C>G p.L142= | Silent (SNP) | VAF 76/385 reads (20%) | catalogued as rs761041692, COSV62279933; called by muse, mutect2, varscan2
- OR6C70 | c.360C>T p.R120= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV59244625; called by muse, mutect2, varscan2
- PEX13 | c.630C>T p.L210= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99692817; called by muse, mutect2, varscan2
- SCO2 | c.714G>A p.T238= | Silent (SNP) | VAF 83/160 reads (52%) | catalogued as rs754644513, COSV99329529; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC63 | c.1983G>A p.Q661= | Silent (SNP) | VAF 31/199 reads (16%) | catalogued as rs1041616172, COSV100938375; called by muse, mutect2, varscan2
- SIDT1 | c.1695C>T p.C565= | Silent (SNP) | VAF 60/297 reads (20%) | catalogued as COSV99333882; called by muse, mutect2, varscan2
- SIPA1L1 | c.3246G>A p.P1082= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as rs780788529, COSV100665515; called by muse, mutect2, varscan2
- THEMIS | c.1248C>T p.I416= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as COSV64071345; called by muse, mutect2, varscan2
- THUMPD1 | c.741C>T p.V247= | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as COSV101189713, COSV67263132; called by muse, mutect2, varscan2
- TP53I11 | c.6G>A p.A2= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs772104595, COSV57532735; called by muse, mutect2
- WAC | c.1719A>T p.G573= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100611021; called by muse, mutect2, varscan2
- ZC3H12A | c.1485C>T p.H495= | Silent (SNP) | VAF 69/178 reads (39%) | catalogued as COSV100897706; called by muse, mutect2, varscan2
- ANKIB1 | c.-137G>T | 5'UTR (SNP) | VAF 7/105 reads (7%) | catalogued as COSV99729013; called by muse, mutect2
- EEF1D | c.-7-2473G>T | Intron (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100414698; called by muse, mutect2, varscan2
- FAM184A | c.1815+289A>G | Intron (SNP) | VAF 33/106 reads (31%) | catalogued as rs1171568009, COSV100137773; called by muse, mutect2, varscan2
- MTUS1 | c.2449+1817C>G | Intron (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100029397; called by muse, mutect2, varscan2
- NOVA1 | c.519+1855G>T | Intron (SNP) | VAF 25/205 reads (12%) | catalogued as COSV57474285, COSV99947544; called by muse, mutect2, varscan2
- POLA1 | c.2947-20841C>A | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
